Somatic mutation profile of tumor specimen TCGA-CJ-5678-01A (aliquot TCGA-CJ-5678-01A-11D-1534-10) from TCGA case TCGA-CJ-5678, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 62.8 years (22,944 days).
Specimen TCGA-CJ-5678-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e8bf9ee-93fe-4619-93e6-088c80b9dac9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5678-11A (Solid Tissue Normal), aliquot TCGA-CJ-5678-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a84552c-0aff-4c66-a1fd-b3402ef19e4d

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 10, Frame Shift Del 9, Nonsense Mutation 3, Intron 2, Frame Shift Ins 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM3 | c.1724A>C p.D575A | Missense Mutation (SNP) | VAF 70/291 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV58642691; called by muse, mutect2, varscan2
- C4orf33 | c.146C>G p.P49R | Missense Mutation (SNP) | VAF 106/355 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV55415758; called by muse, mutect2, varscan2
- C6orf58 | c.576T>G p.Y192* | Nonsense Mutation (SNP) | VAF 174/592 reads (29%) | catalogued as COSV61666431; called by muse, mutect2, varscan2
- CARD6 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV54565894; called by muse, mutect2, varscan2
- CORIN | c.296C>A p.T99K | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV56690539, COSV99903604; called by muse, mutect2, varscan2
- DDX20 | c.2054C>A p.S685Y | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as COSV63778951; called by muse, mutect2, varscan2
- DDX3Y | c.474T>A p.F158L | Missense Mutation (SNP) | VAF 208/336 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60176853; called by muse, mutect2, varscan2
- GRM1 | c.2161G>T p.V721L | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.39); catalogued as COSV51137715; called by muse, mutect2, varscan2
- INO80D | c.2141G>C p.G714A | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV68958750; called by muse, mutect2, varscan2
- ITIH5 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs748393605, COSV56903397; called by muse, mutect2
- KMT2C | c.1049C>G p.P350R | Missense Mutation (SNP) | VAF 57/485 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51434251; called by muse, varscan2
- LRRC52 | c.417A>T p.L139F | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV54231984; called by muse, mutect2, varscan2
- NLRP2 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs368936931; called by muse, mutect2, varscan2
- NR1I2 | c.252C>A p.C84* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs1343552901, COSV61978172; called by muse, mutect2, varscan2
- PPP2CB | c.635C>A p.S212* | Nonsense Mutation (SNP) | VAF 39/147 reads (27%) | catalogued as COSV55328406; called by muse, mutect2, varscan2
- SPPL2B | c.1628C>G p.S543C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV71765503; called by muse, mutect2, varscan2
- STYXL2 | c.2657A>T p.D886V | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV54804567; called by muse, mutect2, varscan2
- TP53TG5 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV65577379; called by muse, mutect2, varscan2
- TTC14 | c.435G>C p.L145F | Missense Mutation (SNP) | VAF 54/1114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56010774; called by muse, mutect2
- UBA5 | c.398A>G p.H133R | Missense Mutation (SNP) | VAF 127/451 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1227261360, COSV53904590; called by muse, mutect2, varscan2
- UBR5 | c.5525T>C p.M1842T | Missense Mutation (SNP) | VAF 93/341 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV55285392; called by muse, mutect2, varscan2
- UNKL | c.1696A>G p.N566D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV50189972; called by muse, mutect2, varscan2
- ZHX3 | c.2015C>G p.T672S | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV58382945, COSV58389030; called by muse, mutect2, varscan2
- ZHX3 | c.2014A>G p.T672A | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV58382951; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1186A>G p.K396E | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52852304; called by muse, mutect2, varscan2
- ZNF83 | c.58A>T p.N20Y | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV56529618; called by muse, mutect2, varscan2
- CASP1 | c.813_818del p.S272_L273del (on ENST00000436863 / NM_033292.4; = p.S251_L252del on NM_001223.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 28/197 reads (14%) | called by mutect2, pindel, varscan2
- DNAJC14 | c.951del p.G318Dfs*35 | Frame Shift Del (DEL) | VAF 27/125 reads (22%) | called by mutect2, pindel, varscan2
- FMN1 | c.2234_2237del p.E745Vfs*12 (on ENST00000616417 / NM_001277313.2; = p.E522Vfs*12 on NM_001103184.4) | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel
- GBP7 | c.959_960del p.Q320Lfs*2 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- MAP2K3 | c.562del p.H188Tfs*4 (on ENST00000342679 / NM_145109.3; = p.H159Tfs*4 on NM_002756.4) | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- MED1 | c.747del p.S250Lfs*4 | Frame Shift Del (DEL) | VAF 62/264 reads (23%) | called by mutect2, pindel, varscan2
- NSUN2 | c.712del p.V238Wfs*14 | Frame Shift Del (DEL) | VAF 34/128 reads (27%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3310dup p.A1104Gfs*3 (on ENST00000296302 / NM_001366071.2; = p.A1079Gfs*3 on NM_018313.5) | Frame Shift Ins (INS) | VAF 96/302 reads (32%) | called by mutect2, pindel, varscan2
- SYNE1 | c.24286_24287del p.V8096Hfs*15 (on ENST00000367255 / NM_182961.4; = p.V8025Hfs*15 on NM_033071.3) | Frame Shift Del (DEL) | VAF 62/218 reads (28%) | called by pindel, varscan2
- TRPM3 | c.5021_5022del p.R1674Qfs*33 (on ENST00000357533 / NM_001366142.2; = p.R1529Qfs*33 on NM_020952.6) | Frame Shift Del (DEL) | VAF 39/155 reads (25%) | called by mutect2, pindel, varscan2
- YTHDC2 | c.2411_2418del p.L804* | Frame Shift Del (DEL) | VAF 254/664 reads (38%) | called by mutect2, pindel, varscan2
- CD209 | c.823C>A p.R275= | Silent (SNP) | VAF 42/147 reads (29%) | catalogued as rs562144201, COSV52652802; called by muse, mutect2, varscan2
- ESR1 | c.1284G>T p.L428= | Silent (SNP) | VAF 122/404 reads (30%) | catalogued as COSV52789529; called by muse, mutect2, varscan2
- GATD1 | c.603T>C p.N201= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV60592332; called by muse, mutect2, varscan2
- GLB1L3 | c.1848G>A p.Q616= | Silent (SNP) | VAF 136/560 reads (24%) | catalogued as COSV68392664; called by muse, mutect2, varscan2
- MUC1 | c.3429C>A p.I1143= (on ENST00000611571 / NM_001371720.1; = p.I154= on NM_002456.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV58113426; called by muse, mutect2, varscan2
- OR4C12 | c.774C>A p.R258= | Silent (SNP) | VAF 57/258 reads (22%) | catalogued as COSV58859844; called by muse, mutect2, varscan2
- PRICKLE4 | c.138C>T p.A46= (on ENST00000359201; = p.A86= on NM_013397.6) | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV59254918; called by muse, mutect2, varscan2
- RASGEF1C | c.1227A>G p.K409= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as COSV63180198; called by muse, mutect2, varscan2
- TRPM5 | c.918C>T p.I306= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- ZNF106 | c.1989C>T p.H663= | Silent (SNP) | VAF 101/335 reads (30%) | catalogued as COSV55516208; called by muse, mutect2, varscan2
- ADGRE4P | n.354C>T | RNA (SNP) | VAF 124/441 reads (28%) | catalogued as rs1189999584; called by muse, mutect2, varscan2
- CASP10 | c.1415+8118C>A | Intron (SNP) | VAF 56/250 reads (22%) | catalogued as COSV53777798; called by muse, mutect2, varscan2
- PHACTR4 | c.17-20678G>T | Intron (SNP) | VAF 113/283 reads (40%) | catalogued as COSV65783798; called by muse, mutect2, varscan2
